Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4854, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4854-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Accession Number: [REDACTED]
Type: Surgical Pathology
Specimen Type: Lymph node biopsy (non-heme)
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

Report Status: [REDACTED]

CASE: [REDACTED]

PATIENT: [REDACTED]

Resident: [REDACTED]

Pathologist: [REDACTED]

TCGA-CZ-4854

PATHOLOGIC DIAGNOSIS:

REGIONAL LYMPH NODE, BIOPSY (including FSA):
Two lymph nodes, negative for tumor (0:2).

RIGHT KIDNEY, NEPHRECTOMY:

RENAL CELL CARCINOMA, clear cell type (5.7 cm), Fuhrman nuclear grade II.
Tumor is confined to the kidney.
No lymphovascular invasion is identified.
Vascular, ureteric, and soft tissue margins are negative for tumor.
Simple cortical cyst.

AJCC Classification (6th Edition): T1b N0 MX

Selected slides of this case were reviewed by [REDACTED]
Service, who concurs.

RENAL PATHOLOGY EVALUATION OF NON-NEOPLASTIC RENAL PARENCHYMA [REDACTED]

DIFFUSE MESANGIAL EXPANSION WITH FOCAL NODULAR GLOMERULOSCLEROSIS
CONSISTENT WITH EARLY DIABETIC NEPHROPATHY (SEE NOTE).

FOCAL GLOBAL AND SEGMENTAL GLOMERULOSCLEROSIS, MOST LIKELY SECONDARY TO
FUNCTIONAL AND STRUCTURAL ADAPTATIONS (SEE NOTE).

SEVERE ARTERIAL AND HYALINE ARTERIOLAR SCLEROSIS (SEE NOTE).

NOTE:

The non-neoplastic renal parenchyma shows changes consistent with early diabetic glomerulosclerosis, as well as extensive global glomerulosclerosis and severe vascular scarring. Prominent vascular sclerosis has traditionally been considered part of the structural changes seen in diabetic patients with kidney disease, although it is important to note that these lesions are non-specific, and they can result from a number of etiologies, including the microangiopathies from inherited or acquired procoagulant states, the healed phases of hemolytic-uremic syndrome or thrombotic thrombocytopenic purpura, angiotoxic drugs, radiation, and other metabolic diseases. Therefore, a primary form of vascular injury superimposed on renal damage from diabetes mellitus cannot be definitively ruled out.

Segmental or global glomerulosclerosis is frequently the consequence of adaptations for hemodynamic changes and glomerular hypertrophy following loss of functioning nephrons. Such loss of nephrons is often the result of an independent primary glomerular, tubular, interstitial, neoplastic, or vascular disease. These patients often show subtotal visceral epithelial cell foot process effacement ultrastructurally, and they may be at risk for persistent sub-nephrotic proteinuria; they do not often manifest hypoalbuminemia or edema. In this patient, diabetic sclerosis, severe vascular scarring, healed episodes of interstitial nephritis from antineoplastic or pharmaceutical agents, and the resected mass all may have contributed to nephron loss with subsequent glomerular obsolescence.

Dr. [REDACTED] Renal Pathologist, has reviewed the non-neoplastic renal parenchyma.

MICROSCOPIC DESCRIPTION:

The section for light microscopy (block B7) contains cortex and medulla, and

[page 2 of 4]
was evaluated using HE, PAS, Jones silver methenamine, and trichrome (AFOG) stains. There are 187 glomeruli present, of which 47 (25.1%) are globally sclerosed and 3 are segmentally sclerosed. Many glomeruli show enlargement of the glomerular tuft with diffuse sclerosis of the mesangium and slight increase in mesangial cells. A few mesangial areas reveal early nodular expansion. The glomerular capillary wall basement membranes are often thickened, and there are occasional double contours; spikes or craters are not prominent. The interstitium contains a scattered, mild mononuclear inflammatory infiltrate. Approximately 40% of the sample shows tubular atrophy and interstitial fibrosis. Arteries reveal severe intimal and medial sclerosis with narrowing of the arterial lumen. Afferent and efferent arteriolar walls show prominent hyaline degeneration and sclerosis, with extensive "onion-skinning."

CLINICAL DATA:

History: [REDACTED] with incidental finding of R renal mass, Hx of TCC (bladder).

Operation: Nephrectomy.

Operative Findings: None given.

Clinical Diagnosis: None given.

TISSUE SUBMITTED:

A/1. Regional lymph node.

B/2. Right kidney.

O.R. CONSULTATION:

SPECIMEN LABELED: "#1. REGIONAL LYMPH NODE" (INCLUDING FSA1-2):

Lymph nodes with fat replacement and focus of atypical cells with eosinophilic cytoplasm, pending permanent sections and immunohistochemistry, most likely muscle. Dr. [REDACTED] reviewed the case and concurs with the diagnosis.

OR Consultation by: [REDACTED]

Resident: [REDACTED]

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnos(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, Received fresh in the frozen section lab labeled "#1. Regional lymph node", and consists of a single fragment of yellow/red soft tissue (2.6 x 0.9 x 0.6 cm) within which two lymph node candidates (0.5 x 0.5 x 0.4 cm and 0.9 x 0.6 x 0.5 cm) are identified. The smaller lymph node candidate is frozen as FSA1 and the larger is frozen as FSA2.

Micro A1: "FSA1" remnant, 1 frag, [REDACTED]

Micro A2: "FSA2" remnant, 1 frag, [REDACTED]

Micro A3: Non frozen tissue, 2 frags [REDACTED]

Part B, Received fresh in frozen section lab labeled "#2. Right kidney", and consists of a right radical nephrectomy specimen (1121.5 grams; 27.5 x 14 x 6.2 cm), to include right kidney (12.0 x 7.2 x 7.0 cm), renal artery (1.8 cm in length x 0.5 cm in diameter), renal vein (0.4 cm in length x 0.7 cm in diameter), ureter (10 cm in length x 0.3 cm in diameter), abundant paranephritic fat and Gerota's fascia (13 x 9 x 0.1 cm). An adrenal gland is not present. Within the mid pole, there is a yellow/red, focally hemorrhagic, solid partially encapsulated mass (5.7 x 5.2 x 4.3 cm), 10.3 cm of the ureteral margin, 6.5 cm from the renal artery margin, and 2.5 cm of the renal vein margin. The mass grossly appears to impinge upon but not involve the renal pelvis or caliceal system and grossly abuts but does not invade the renal capsule (at the anterior lateral aspect). There is a 1.2 x 1.0 x 0.6 cm clear fluid filled cortical cyst at the anterior/superior aspect of the kidney which abuts the Gerota's fascia (inked black). There are two additional cystic structures (1.0 x 0.6 x 0.5 cm and 1.5 x 1.0 x 1.0 cm) present in the anterior aspect of the kidney adjacent to the renal mass which display no excrescences. The remainder of the parenchyma is red/tan with a well defined cortical medullary junction. The pelvis and ureter display a tan, glistening lining [REDACTED]. Representative sections of the tumor are submitted to [REDACTED].

[page 3 of 4]
Pathology Report

cytogenetics and electron microscopy. Representative renal cortex is held for electron microscopy and immunofluorescence. Additionally, representative sections of the renal mass and normal kidney are submitted to the tissue bank for special studies. Photographs are taken. No lymph nodes are identified.

Micro B1: Renal vein, renal artery and ureteral margins (en face), 3 frags,
Micro B2-B3: Renal mass at deepest extension, 2 frags,
Micro B4: Renal mass in relationship to pelvis, artery and largest cyst, 1 frag,
Micro B5: Renal mass in relation to adjacent normal parenchyma and additional pelvis, 1 frag,
Micro B6: Cyst adjacent to Gerota's fascia and relation to renal mass, 1 frag,
Micro B7: Cortical medullary junction to include additional smaller cyst, 1 frag,
Micro B8: Ureter and pelvis, 1 frag,

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

Resident Review by
Final Diagnosis by

[page 4 of 4]
Pathology Report

Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist
[REDACTED]

Report Status: [REDACTED]

KARYOTYPE:

42-53,X,-Y,del(1)(p22),del(3)(p21),add(6)(q27),,+7,-8,-10,+11,+12,-17,+19,add(19)(q13),+20,+21,+mar[cp9]/46,XY[4]

METAPHASES COUNTED: 14

ANALYZED: 12

SCORED: 0

BANDING: GTG

INTERPRETATION:

9 of 14 metaphases contained the clonal aberrations that included deletion of the chromosome 3 short arm (3p). This aberration is a characteristic finding in renal cell carcinoma, clear cell type.

The abnormal karyotype was seen in metaphases from tumor parts labeled T1 and T3.

COMMENTS:

INDICATION FOR TEST:
Renal cell carcinoma

CLINICAL DATA:
[REDACTED] year old male

REPORT by [REDACTED]
Final Diagnosis by [REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file 13625ed6-e090-49eb-a4aa-27595b4d8f6f (TCGA-CZ-4854.76856B3C-9F38-4FEE-A8FB-9758E92F337E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).